Somatic mutation profile of tumor specimen MP2PRT-PARPZJ-TBP1-A (aliquot MP2PRT-PARPZJ-TBP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARPZJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (648 days).
Specimen MP2PRT-PARPZJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a93584a3-b7a7-4368-bb89-de0a01e99e42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPZJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPZJ-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6360bbf0-28b1-48e0-8d09-b2cd0b135f63

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs763323193; ClinVar: uncertain significance; called by muse, mutect2
- TDRD9 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328206343, COSV59145979; called by muse, mutect2
- C14orf39 | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CXADR | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 21/221 reads (10%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OR8K1 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- SHISA2 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- IGHV4-59 | c.350delinsCCCCC p.*117delinsAP | Silent (INS) | VAF 34/116 reads (29%) | called by pindel, varscan2*
- LRRC53 | c.3222A>G p.L1074= | Silent (SNP) | VAF 15/273 reads (5%) | called by muse, mutect2
- PMFBP1 | c.2712C>T p.V904= (on ENST00000537465; = p.V899= on NM_031293.3) | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as rs746657434; called by muse, mutect2, varscan2
- SIGLEC1 | c.144C>T p.D48= | Silent (SNP) | VAF 60/298 reads (20%) | catalogued as rs374738632; called by muse, mutect2, varscan2
